Gene-level copy-number profile of tumor specimen ALCH-B4FB-TTP1-A from ALCHEMIST case ALCH-B4FB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.7 years (19,233 days).
Specimen ALCH-B4FB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 15c760f3-a5b7-4d8a-b4cd-e05af0295281.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4FB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/409ac3ee-229a-4c09-a694-9b81e3d10595

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 3,534; copy number 2: 55,242; copy number 3: 27; copy number 4: 21; copy number 5: 23; copy number 6: 23.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,412,418–6,466,175, 5 genes (within-gene range 0–2): HES2, ESPN, MIR4252, AL031848.1, TNFRSF25.
- chr2:232,479,827–232,487,834, 1 gene: ECEL1.
- chr5:524,109–535,882, 2 genes (within-gene range 0–2): AC106772.2, MIR4456.
- chr6:26,896,952–26,898,777, 1 gene (within-gene range 0–2): POM121L6P.
- chr11:67,006,778–67,072,017, 3 genes: SYT12, MIR6860, RHOD.
- chr12:30,926,428–31,006,010, 2 genes: TSPAN11, AC008013.1.
- chr12:132,424,504–132,425,208, 1 gene: AC148476.1.
- chr15:41,825,099–41,894,053, 7 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr17:75,498,548–75,498,628, 1 gene (within-gene range 0–2): MIR6785.
- chr22:18,533,646–18,653,617, 8 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:29,705,256–29,719,859, 2 genes: AC004882.1, AC004882.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:25,195,216–27,425,289, 46 genes, copy number 5–6 (within-gene range 4–6): ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2.

Autosomal genes at a single copy (total copy number 1): 703. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
